Surgical pathology report (de-identified scan), TCGA case TCGA-EE-A2M6, project TCGA-SKCM (Skin Cutaneous Melanoma), tissue source site University of Sydney, specimen TCGA-EE-A2M6-06A (Metastatic).

[page 1 of 2]
PathNet History Upload External
Client

DOB/Age/Sex:
Location:
Requested by:
Requested on:
Specimen Rcvd:
Accession No.:
Copies to:

ARCHIVAL HISTOPATHOLOGY SUPPLEMENTARY REPORT

Accession Number:

Collected Date:

SUPPLEMENTARY HISTORICAL REQUEST DETAIL

MRN

Req Dr:

SUPPLEMENTARY REPORT

A letter was received from Prof. [redacted]
clarification of the original report of this case.

regarding

Four of twenty lymph nodes contain metastatic malignant melanoma. As each of these metastatic foci are >2mm in maximum dimension none of these represent micrometastases. The remaining 16 lymph nodes show no evidence of malignancy.

Electronic signature

SUPPLEMENTARY SUMMARY / KEY WORDS

1CD-0-3

Melanoma, NOS 8720/3

Site: lymph node, axillary

C 77.3

lw
8/24/11

[page 2 of 2]
Requested by: N/A

MRN/Name:

Location:

Accession:

ARCHIVAL HISTOPATHOLOGY REPORT

Accession Number:

Collected Date:

HISTORICAL REQUEST DETAILS

CLINICAL NOTES

Melanoma Hx. Now axillary mets.

SPECIMEN INFORMATION

Radical axillary dissection (level III) including lesser pectoral muscle.
(Double) stitch marks apex of specimen.

MACROSCOPIC DESCRIPTION

"Right axillary contents double stitch marks apex". A piece of fibroadipose tissue 165 x 110 x 75mm with attached skeletal muscle 70 x 50 x 40mm. A double suture marks the apex. Lymph nodes were dissected from the apex. The specimen includes a number of enlarged centrally necrotic lymph nodes which are macroscopically involved by tumour up to 45mm across.

- A. 22 apical nodes whole.
- B. 4 whole nodes.
- C. Portion of 1 large node.
- D. 4 nodes whole.
- E. 1 node bisected.
- F. 3 nodes whole.
- G. Section of one large macroscopically involved node.
- H. 1 node bisected.
- J. Part of one large macroscopically involved node.
- K. 1 node whole.
- L. 1 node bisected.

MICROSCOPIC REPORT

"Right axillary contents double stitch marks apex". Four of twenty lymph nodes show involvement by large pleomorphic malignant cells consistent with metastatic malignant melanoma. No extracapsular spread of tumour is seen. None of the involved nodes contain micrometastases (<2mm).

Immunohistochemical stains show focal 2+ positive staining for S100, HMB45 and Melan A. This immunohistochemical profile is characteristic of malignant melanoma.

SEE ADDENDUM REPORT:

Electronic signature

Verified by

SUMMARY / KEY WORDS

Lymph node - malignant melanoma
Haematopathology resection

Source: NCI Genomic Data Commons file 218357ab-2c9d-4dcd-8101-c8fbfa437099 (TCGA-EE-A2M6.C1B5AEF2-669A-4153-BD01-A0280D98F277.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).